Gene-level copy-number profile of tumor specimen TCGA-G5-6233-01A from TCGA case TCGA-G5-6233, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 74.4 years (27,190 days).
Specimen TCGA-G5-6233-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.5e7267fd-0abe-4cd3-beaa-afaf3dfa9478.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G5-6233-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df416f99-e068-45e2-90a5-5cf29b7eb41e

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 31,294; copy number 2: 22,223; copy number 3: 4,910; copy number 4: 637; copy number 5: 754.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-G5-6233-01): tumor purity 0.57, ploidy 2.65, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,301 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:104,590,733–105,804,539, 1 gene, copy number 3 (within-gene range 2–3): ZFPM2.
- chr8:104,981,164–145,066,685, 590 genes, copy number 3 (broad region; genes not listed).
- chr11:167,784–54,725,816, 1,182 genes, copy number 3 (broad region; genes not listed).
- chr12:66,767–63,360,037, 1,624 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 4–5 (broad region; genes not listed).
- chr15:99,805,793–101,933,350, 63 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr20:87,250–16,053,197, 287 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28,873. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
